Somatic mutation profile of tumor specimen 0DVF8X from CCDI case PBCMUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,666 days).
Specimen 0DVF8X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13779e6e-e16d-4679-8058-ec1f338117a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVF8Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04d0a807-971c-4242-9ea8-02cbc665fc21

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Nonsense Mutation 2, Missense Mutation 1, Intron 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFRA3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 227/553 reads (41%) | catalogued as rs1371452874; called by muse, mutect2, varscan2
- COL6A3 | c.5578T>G p.S1860A | Missense Mutation (SNP) | VAF 64/896 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- LCK | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 184/429 reads (43%) | called by muse, mutect2, varscan2
- ATP6V1FNB | c.315C>T p.H105= | Silent (SNP) | VAF 146/435 reads (34%) | catalogued as rs1033789439, COSV99925965; called by muse, mutect2, varscan2
- FLT3 | c.1215G>A p.K405= | Silent (SNP) | VAF 302/846 reads (36%) | catalogued as COSV54050621; called by muse, mutect2, varscan2
- MUC16 | c.26481G>T p.G8827= | Silent (SNP) | VAF 38/658 reads (6%) | catalogued as rs1481650593, COSV67500943; called by muse, mutect2
- FGD5 | c.3670-83C>A | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as COSV53249047; called by muse, varscan2
- PLAC9 | chr10:80132695 C>G | 5'Flank (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- SCN5A | c.*97G>A | 3'UTR (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
